Gene-level copy-number profile of specimen HCM-SANG-0294-C15-85A from HCMI case HCM-SANG-0294-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0294-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ac4ade96-e22a-4053-a533-12107de34918.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0294-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/e3dfc1b9-da5f-41ac-92a0-5835e7625b0e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 1,413; copy number 2: 21,610; copy number 3: 27,080; copy number 4: 6,514; copy number 5: 1,188; copy number 6: 939; copy number 7: 38; copy number 8: 40; copy number 9: 14; copy number 10: 2; copy number 14: 30.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr21:13,349,265–13,489,176, 5 genes: FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P.
- chr21:13,665,868–14,210,891, 26 genes: GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1, FAM207CP, GXYLT1P2, CNN2P7, ZNF114P1, CYP4F29P, SNX18P13, ANKRD20A11P, RHOT1P2, RNU6-954P, NF1P3, PPP6R2P1, FRG2MP, AP001347.1, ANKRD20A18P, RNA5SP488, AP001347.2, LIPI, ERLEC1P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 124 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,095,176–12,099,536, 1 gene, copy number 9: DEFB108D.
- chr12:68,746,125–69,823,204, 30 genes, copy number 14 (within-gene range 1–14): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP.
- chr16:69,187,129–70,686,053, 60 genes, copy number 7–10 (within-gene range 5–10): SNTB2, Y_RNA, AC026474.1, AC026464.4, VPS4A, COG8, PDF, AC026464.6, AC026464.3, AC026464.1, NIP7, TMED6, TERF2, CYB5B, AC026464.5, AC026464.2, NFAT5, MIR1538, AC009032.1, AC012321.1, NQO1, AC092115.2, AC092115.3, NOB1, AC092115.1, WWP2, SNORA62, MIR140, CLEC18A, AC026468.1, PDXDC2P-NPIPB14P, NPIPB14P, PDXDC2P, MIR1972-2, AC009022.1, PDPR, AC009060.1, CLEC18C, AC009060.2, SMG1P7, EXOSC6, AARS1, RN7SL279P, DDX19B, AC012184.2, AC012184.3, DDX19A, AC012184.4, ST3GAL2, AC012184.1, RPS27P26, RNU6-23P, FCSK, COG4, SF3B3, SNORD111B, SNORD111, IL34, MTSS2, AC020763.4.
- chr18:316,737–1,408,344, 33 genes, copy number 7 (within-gene range 5–7): COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2.

Autosomal genes at a single copy (total copy number 1): 1,352. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
